Somatic mutation profile of tumor specimen C3L-07437-55 (aliquot CPT0409210002) from CPTAC case C3L-07437, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 75.1 years (27,419 days).
Specimen C3L-07437-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f88ecfa4-9e19-4c2f-afd1-74e76c026fcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07437-50 (Buccal Cell Normal), aliquot CPT0409180001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c071985-5419-48be-8dfd-c10f51fcdfd8

The open-access MAF lists 13 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, 5'UTR 3, Missense Mutation 2, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH11 | c.7229G>T p.C2410F | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100179674; called by muse, varscan2
- RYR2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as rs763802687, COSV63703359; called by muse, mutect2
- SLCO1A2 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1338304123, COSV56601162; called by muse, mutect2
- CCDC96 | c.834C>T p.P278= | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as rs917909855; called by muse, mutect2, varscan2
- DOCK2 | c.27G>A p.K9= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56961053; called by muse, mutect2, varscan2
- OR9G1 | c.312A>T p.A104= | Silent (SNP) | VAF 54/262 reads (21%) | called by mutect2, varscan2
- PARP4 | c.3132C>A p.T1044= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs750111492, COSV101131596; called by muse, mutect2
- XPO1 | c.2436G>T p.G812= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- EIF4EBP3 | c.-42C>T | 5'UTR (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- FAAP20 | c.471-706C>T | Intron (SNP) | VAF 20/56 reads (36%) | catalogued as rs995573864; called by muse, mutect2, varscan2
- KLHDC8A | c.-220G>A | 5'UTR (SNP) | VAF 22/102 reads (22%) | catalogued as rs987606015; called by muse, mutect2, varscan2
- SLC26A8 | c.-9T>C | 5'UTR (SNP) | VAF 113/299 reads (38%) | called by muse, mutect2, varscan2
